Somatic mutation profile of tumor specimen TCGA-FG-7636-01A (aliquot TCGA-FG-7636-01A-11D-2086-08) from TCGA case TCGA-FG-7636, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 48.9 years (17,843 days).
Specimen TCGA-FG-7636-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4b49ebf2-3fcf-41d9-b590-374b18b4865f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-7636-10A (Blood Derived Normal), aliquot TCGA-FG-7636-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4f8becf-7d2f-4dc9-bf35-7e28e5754b55

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 25, Silent 8, Frame Shift Del 2, Splice Site 1, Nonsense Mutation 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/106 reads (42%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 27/30 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACVR2A | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54022511; called by mutect2, varscan2
- AGBL2 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV54091990; called by muse, mutect2, varscan2
- ANO8 | c.2393G>A p.R798H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1270438715, COSV50177232, COSV99344375; called by muse, mutect2, varscan2
- AREG | c.286T>C p.Y96H | Missense Mutation (SNP) | VAF 9/268 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV99144380; called by muse, mutect2
- BMP4 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55415974; called by muse, mutect2, varscan2
- CACNA1H | c.1304A>G p.E435G | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61990467; called by muse, mutect2
- CCDC136 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/97 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.274); catalogued as COSV52799543; called by muse, mutect2, varscan2
- FFAR1 | c.361T>C p.C121R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV50052723; called by muse, mutect2, varscan2
- FHDC1 | c.3003G>C p.K1001N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52599870; called by muse, mutect2, varscan2
- GRIN2D | c.2601C>A p.H867Q | Missense Mutation (SNP) | VAF 52/96 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53518746; called by muse, mutect2, varscan2
- GUF1 | c.1480-2A>G p.X494_splice | Splice Site (SNP) | VAF 13/192 reads (7%) | catalogued as COSV55782671; called by muse, mutect2
- IGSF8 | c.116G>A p.R39H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs190351074, COSV58758030, COSV58758532; called by muse, mutect2, varscan2
- KMT2D | c.9926C>T p.S3309F | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV56439551; called by muse, mutect2, varscan2
- LRP1B | c.2812C>T p.R938C | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs921851032, COSV67214705; called by muse, mutect2, varscan2
- MUC16 | c.29864C>G p.T9955S | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.849); catalogued as COSV67449074, COSV67465843, COSV67502802; called by muse, mutect2, varscan2
- NCOA7 | c.1141T>C p.S381P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV57655424; called by muse, mutect2
- NLRP9 | c.1016C>T p.T339M | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV60460536; called by muse, mutect2, varscan2
- NOTCH4 | c.1203C>A p.C401* | Nonsense Mutation (SNP) | VAF 15/103 reads (15%) | catalogued as COSV66680653; called by muse, mutect2, varscan2
- NPY1R | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV56714483; called by muse, mutect2, varscan2
- OR2M3 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71759045; called by muse, mutect2
- PKLR | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.294); catalogued as rs768210809, CM061899, COSV100712907, COSV61361108; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRH | c.3152T>A p.F1051Y | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.175); catalogued as COSV54745415; called by muse, mutect2, varscan2
- SLC10A6 | c.221G>A p.C74Y | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56721621; called by muse, mutect2, varscan2
- SLITRK5 | c.1517A>G p.N506S | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.759); catalogued as COSV61522901, COSV61523562; called by muse, mutect2, varscan2
- SMARCC1 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54377697; called by muse, mutect2
- ZNF143 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs758635813, COSV55180041; called by muse, varscan2
- ATRX | c.5790_5796del p.K1932Gfs*21 | Frame Shift Del (DEL) | VAF 87/138 reads (63%) | called by mutect2, pindel, varscan2
- DGKH | c.2822del p.N941Tfs*6 | Frame Shift Del (DEL) | VAF 34/86 reads (40%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.7_14dup p.D5Efs*52 | Frame Shift Ins (INS) | VAF 46/160 reads (29%) | called by mutect2, varscan2
- HPR | c.681A>G p.G227= | Silent (SNP) | VAF 9/181 reads (5%) | catalogued as COSV57182602; called by muse, mutect2
- KLHL30 | c.645G>A p.L215= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV59975613; called by muse, mutect2, varscan2
- MUC16 | c.18876A>T p.T6292= | Silent (SNP) | VAF 25/177 reads (14%) | catalogued as COSV67465849; called by muse, mutect2, varscan2
- OR2T33 | c.672G>C p.L224= | Silent (SNP) | VAF 4/64 reads (6%) | called by muse, mutect2
- PLEKHN1 | c.1095C>T p.R365= (on ENST00000379409; = p.R313= on NM_032129.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs753869694, COSV58021851; called by muse, mutect2, varscan2
- SRMS | c.213T>C p.S71= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV53920726; called by muse, mutect2, varscan2
- TET1 | c.6045C>T p.H2015= | Silent (SNP) | VAF 100/271 reads (37%) | catalogued as rs757569954, COSV65384773; called by muse, mutect2, varscan2
- ZBTB49 | c.1005G>A p.K335= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV61925075, COSV61925386; called by muse, mutect2
